Somatic mutation profile of tumor specimen 0DVZ1M from CCDI case PBCNJT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 0.1 years (40 days).
Specimen 0DVZ1M: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82bb7475-28ea-4d4d-9ce8-047b00f2e36e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVZ0Q (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b69db6b-b3e1-4456-8cb2-2f2b5628325d

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SAMD9 | c.2084A>C p.Y695S | Missense Mutation (SNP) | VAF 100/376 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- TACC2 | c.6172G>A p.D2058N (on ENST00000334433; = p.D136N on NM_006997.4) | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SLC22A12 | c.36C>G p.G12= | Silent (SNP) | VAF 64/254 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.54324C>T p.D18108= (on ENST00000591111; = p.D10684= on NM_003319.4) | Silent (SNP) | VAF 140/363 reads (39%) | catalogued as rs587780491; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
